Somatic mutation profile of tumor specimen TCGA-34-2596-01A (aliquot TCGA-34-2596-01A-01D-1522-08) from TCGA case TCGA-34-2596, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.0 years (25,574 days).
Specimen TCGA-34-2596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 942e58f5-d4e6-4f50-854d-28346673a1a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2596-11A (Solid Tissue Normal), aliquot TCGA-34-2596-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a654b6c-4a35-4fde-959f-2a8af49bf743

The open-access MAF lists 279 somatic variants for this specimen: 202 protein-altering or splice-affecting, 72 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 72, Nonsense Mutation 14, Frame Shift Del 5, Splice Site 5, Frame Shift Ins 4, RNA 3, Intron 2, Translation Start Site 1, In Frame Del 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 30/119 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519921, COSV67960034, COSV67960332, COSV67961305; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SYT13 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 37/73 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50072436, COSV50073637; called by muse, mutect2, varscan2
- ABCA9 | c.1309T>C p.F437L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV60624659; called by muse, mutect2, varscan2
- ABHD13 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65534761, COSV65534896; called by muse, mutect2
- ACOX3 | c.1924G>C p.D642H | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62711959; called by muse, mutect2, varscan2
- ACTL9 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs782777098, COSV61005735; called by muse, mutect2, varscan2
- ADAM9 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs147636313; called by muse, mutect2, varscan2
- ADAMTS17 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51480229; called by muse, mutect2, varscan2
- AKAP11 | c.4498G>T p.E1500* | Nonsense Mutation (SNP) | VAF 89/225 reads (40%) | catalogued as COSV50296912; called by muse, mutect2, varscan2
- AMPH | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV100341604; called by mutect2, varscan2
- ANKRD11 | c.2676C>G p.S892R | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as COSV56360693; called by muse, mutect2, varscan2
- APOA5 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769230421, COSV57063149; called by muse, mutect2, varscan2
- ARFGEF1 | c.3508G>C p.V1170L | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51608294; called by muse, mutect2, varscan2
- ARGLU1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs761041918, COSV62271543; called by muse, mutect2, varscan2
- ARID2 | c.4391G>A p.R1464H | Missense Mutation (SNP) | VAF 85/401 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); catalogued as rs770601353, COSV57603414; called by muse, mutect2, varscan2
- ATF4 | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV57478918; called by muse, mutect2, varscan2
- ATG13 | c.1348-1G>C p.X450_splice (on ENST00000359513 / NM_001346321.1; = p.X413_splice on NM_014741.4 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 94/240 reads (39%) | catalogued as COSV56319316; called by muse, mutect2, varscan2
- ATP4A | c.796C>A p.Q266K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV52867955; called by muse, mutect2, varscan2
- BFSP2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV56588805; called by muse, mutect2, varscan2
- BMPR2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs777927015, COSV65807366; called by mutect2, varscan2
- BRAF | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 304/474 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56174024; called by muse, mutect2, varscan2
- BRINP3 | c.1818G>T p.Q606H | Missense Mutation (SNP) | VAF 181/666 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1471961126, COSV66523813; called by muse, mutect2, varscan2
- C12orf50 | c.1015A>G p.R339G | Missense Mutation (SNP) | VAF 100/332 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV53895191; called by muse, mutect2, varscan2
- C2orf16 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV68646040; called by muse, mutect2, varscan2
- C6 | c.1524G>T p.R508S | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV54706817, COSV54709914; called by muse, mutect2, varscan2
- CACNA1F | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1242467349, COSV59904401; called by muse, varscan2
- CALCR | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745444864, COSV64008031; called by muse, mutect2, varscan2
- CBLN1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV54653505; called by muse, mutect2, varscan2
- CCM2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51848265; called by muse, mutect2, varscan2
- CD1D | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63808990, COSV63809555; called by muse, mutect2, varscan2
- CDH23 | c.9350T>C p.M3117T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV56462904; called by muse, mutect2, varscan2
- CEP72 | c.692-2A>G p.X231_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV53792650; called by muse, mutect2
- CFAP251 | c.2927G>C p.R976T | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56610378; called by muse, mutect2, varscan2
- CFAP46 | c.7783G>T p.A2595S | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV54152244; called by muse, mutect2, varscan2
- CHAMP1 | c.1987A>G p.I663V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782559791, COSV63522339; called by muse, mutect2, varscan2
- CLCN2 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55601093, COSV55601563; called by muse, mutect2, varscan2
- CLSTN1 | c.1003G>A p.A335T (on ENST00000377298 / NM_001009566.3; = p.A325T on NM_014944.4) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.65); PolyPhen benign (0.075); catalogued as COSV63648095; called by muse, mutect2, varscan2
- CNOT2 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV57502658; called by muse, mutect2, varscan2
- CNTN4 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV61872800; called by muse, mutect2, varscan2
- COL15A1 | c.3561C>A p.D1187E | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.851); catalogued as COSV66644560; called by muse, mutect2, varscan2
- COL19A1 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV59572602; called by muse, mutect2, varscan2
- COLEC12 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 116/193 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68370467; called by muse, mutect2, varscan2
- CORO7 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs200108761, COSV52029950; called by muse, mutect2, varscan2
- CREBRF | c.1650A>T p.K550N | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51633022; called by muse, mutect2, varscan2
- CTSA | c.535T>G p.Y179D | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51942092; called by muse, mutect2, varscan2
- CXCL14 | c.281G>A p.R94H (on ENST00000337225; = p.R82H on NM_004887.5) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs139612389; called by muse, mutect2, varscan2
- CYP2A13 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV57837730; called by muse, mutect2, varscan2
- DCT | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 38/90 reads (42%) | catalogued as COSV65469020; called by muse, mutect2, varscan2
- DENND1B | c.1883A>G p.E628G | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV54148746; called by muse, mutect2, varscan2
- DIRAS2 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759324657, COSV65370326; called by muse, mutect2, varscan2
- DLG2 | c.1011C>A p.D337E | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54638779, COSV54643067; called by muse, mutect2, varscan2
- DNAH11 | c.6665G>C p.R2222P | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60955240; called by muse, mutect2, varscan2
- DNAH7 | c.10795G>T p.G3599W | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56764327; called by muse, mutect2, varscan2
- DNMT3A | c.2632T>C p.S878P | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53051897; called by muse, mutect2, varscan2
- DPPA2 | c.234C>A p.C78* | Nonsense Mutation (SNP) | VAF 84/344 reads (24%) | catalogued as COSV72118070; called by muse, mutect2, varscan2
- ECPAS | c.1360C>G p.Q454E | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52196899; called by muse, mutect2, varscan2
- EFHC2 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV101375487, COSV69553733; called by muse, mutect2, varscan2
- EGF | c.1912A>T p.S638C | Missense Mutation (SNP) | VAF 117/263 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54478561; called by muse, mutect2, varscan2
- EHBP1 | c.2189G>T p.S730I | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.125); catalogued as rs755521829, COSV50419949; called by muse, mutect2, varscan2
- EIPR1 | c.517-2A>T p.X173_splice | Splice Site (SNP) | VAF 28/87 reads (32%) | catalogued as COSV66129657; called by muse, mutect2, varscan2
- ENPEP | c.1561del p.A521Qfs*11 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | catalogued as COSV99487966; called by mutect2, pindel, varscan2
- EPB41L3 | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 89/153 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59453166; called by muse, mutect2, varscan2
- EPHA7 | c.2172+1G>T p.X724_splice | Splice Site (SNP) | VAF 38/91 reads (42%) | catalogued as COSV65182463; called by muse, mutect2, varscan2
- EVPL | c.1550C>G p.S517* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100044397, COSV56910778; called by muse, mutect2, varscan2
- FATE1 | c.478C>A p.H160N | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV64848975; called by muse, mutect2, varscan2
- FBXO22 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV57617450; called by muse, mutect2, varscan2
- FLG | c.2993C>A p.S998Y | Missense Mutation (SNP) | VAF 247/764 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV64241681; called by muse, mutect2, varscan2
- FMN2 | c.2905C>A p.P969T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1490064373, COSV60429880; called by muse, mutect2, varscan2
- GALNTL6 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV72490894; called by muse, mutect2, varscan2
- GNL3L | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV60575886, COSV60576305, COSV60577880; called by muse, mutect2, varscan2
- GOLGB1 | c.4004A>T p.K1335I | Missense Mutation (SNP) | VAF 234/559 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61465669; called by muse, mutect2, varscan2
- GRM6 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51440744; called by muse, mutect2, varscan2
- HDAC9 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as rs761522691, COSV67772931; called by muse, mutect2, varscan2
- HEATR6 | c.2319C>A p.N773K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV51745637; called by muse, mutect2, varscan2
- HNF1A | c.1388A>G p.Q463R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV57461984; called by muse, mutect2, varscan2
- HSP90B1 | c.2341G>C p.E781Q | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV55355297, COSV55355769; called by muse, mutect2, varscan2
- HYAL3 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56497526; called by muse, mutect2, varscan2
- IARS1 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65115156; called by muse, mutect2, varscan2
- IFT52 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65975022; called by muse, mutect2, varscan2
- IGHV6-1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 93/176 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs373934455; called by muse, mutect2, varscan2
- IGLV8-61 | c.194C>A p.T65N | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV66503192; called by muse, mutect2, varscan2
- IGSF9 | c.2812G>C p.D938H (on ENST00000368094 / NM_001135050.2; = p.D922H on NM_020789.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57422237, COSV57424025; called by muse, mutect2
- IL10RA | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV57140558; called by muse, mutect2, varscan2
- IQCB1 | c.851T>C p.M284T | Missense Mutation (SNP) | VAF 157/448 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60437399; called by muse, mutect2, varscan2
- KCNB2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050150; called by muse, mutect2, varscan2
- KIF16B | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61701315, COSV61706002; called by muse, mutect2, varscan2
- KLHL14 | c.978G>T p.L326F | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV63832351; called by muse, mutect2, varscan2
- KLHL23 | c.1075A>T p.R359W | Missense Mutation (SNP) | VAF 124/318 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55867128; called by muse, mutect2, varscan2
- KLHL7 | c.1136C>T p.A379V (on ENST00000339077 / NM_001031710.3; = p.A331V on NM_018846.5) | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated (1); PolyPhen possibly damaging (0.607); catalogued as COSV59161326; called by muse, mutect2, varscan2
- KMT2D | c.16329C>A p.Y5443* | Nonsense Mutation (SNP) | VAF 141/478 reads (29%) | catalogued as COSV56438863; called by muse, mutect2, varscan2
- KNG1 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV53977683; called by muse, mutect2, varscan2
- KRT24 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1224997746, COSV52880224; called by muse, mutect2, varscan2
- LAMC1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51141086; called by muse, mutect2, varscan2
- LGSN | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65726571, COSV65727179; called by muse, mutect2, varscan2
- MORF4L2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 137/210 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV100846405, COSV64610634, COSV64610988; called by muse, mutect2, varscan2
- MUC16 | c.32662G>T p.V10888L | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.089); catalogued as COSV67464969; called by muse, mutect2, varscan2
- MUC16 | c.16405C>T p.P5469S | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV67464976; called by muse, mutect2, varscan2
- MYBPC1 | c.1452-1G>T p.X484_splice (on ENST00000550270 / NM_206820.2; = p.X509_splice on NM_002465.4) | Splice Site (SNP) | VAF 69/297 reads (23%) | catalogued as COSV62252969; called by muse, mutect2, varscan2
- MYBPC1 | c.2341G>T p.D781Y (on ENST00000550270 / NM_206820.2; = p.D788Y on NM_002465.4) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62252980; called by muse, mutect2, varscan2
- MYO7B | c.4139C>A p.A1380D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV67347578; called by muse, mutect2, varscan2
- MYRIP | c.2126A>G p.Y709C | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56868755; called by muse, mutect2, varscan2
- NDRG1 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV60483088; called by muse, mutect2, varscan2
- NES | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV63961021, COSV63962539; called by muse, mutect2, varscan2
- NME9 | c.719A>T p.D240V (on ENST00000333911 / NM_001349024.2; = p.D179V on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/532 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV58618621; called by muse, mutect2, varscan2
- NPHS1 | c.3368G>T p.R1123L | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV62287760, COSV62288416; called by muse, mutect2, varscan2
- NRROS | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs150316796, COSV60745860; called by muse, mutect2, varscan2
- NUP155 | c.2810C>T p.A937V (on ENST00000231498 / NM_153485.3; = p.A878V on NM_004298.4) | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51529774; called by muse, mutect2, varscan2
- OR1L4 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as COSV52340409; called by muse, varscan2
- OR2M7 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 117/383 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58739002; called by muse, mutect2, varscan2
- OR2T10 | c.263A>T p.K88I | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV57896830; called by muse, mutect2, varscan2
- OR4D5 | c.139del p.V47Sfs*2 | Frame Shift Del (DEL) | VAF 85/224 reads (38%) | catalogued as COSV58310318; called by mutect2, pindel, varscan2
- OR4K15 | c.194G>T p.G65V (on ENST00000305051; = p.G41V on NM_001005486.1) | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59301355; called by muse, mutect2, varscan2
- OR8B2 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV66664651; called by muse, mutect2, varscan2
- OR8J3 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV56880694; called by muse, mutect2, varscan2
- PAPPA | c.2513C>G p.P838R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60283040; called by muse, mutect2, varscan2
- PARPBP | c.774T>A p.N258K | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV59673459; called by muse, mutect2, varscan2
- PATZ1 | c.2063G>C p.*688Sext*30 | Nonstop Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV56743656; called by muse, mutect2, varscan2
- PBXIP1 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs760022387, COSV63777196; called by muse, mutect2, varscan2
- PCDHB12 | c.2168del p.G723Vfs*17 | Frame Shift Del (DEL) | VAF 44/151 reads (29%) | catalogued as rs781960815, COSV53394560; called by mutect2, pindel, varscan2
- PCDHGA8 | c.2074T>C p.Y692H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs781200096, COSV53945519; called by muse, mutect2, varscan2
- PDIA5 | c.1554G>T p.E518D | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV60249085; called by muse, mutect2, varscan2
- PLA2G4F | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs779506232, COSV51826835; called by muse, mutect2, varscan2
- PLCB4 | c.3013C>G p.L1005V | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV53801365; called by muse, mutect2, varscan2
- PLCD1 | c.499A>G p.N167D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52184612; called by muse, mutect2, varscan2
- PRELP | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs147252422, COSV100557816; called by muse, mutect2, varscan2
- PRKCI | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV55518932; called by muse, mutect2, varscan2
- PRUNE2 | c.6677C>G p.P2226R | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV65041403; called by muse, mutect2, varscan2
- RASGEF1C | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV63180479; called by muse, mutect2, varscan2
- RASGRF1 | c.1895T>A p.V632D | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67249959; called by muse, mutect2, varscan2
- RGL1 | c.1117A>T p.T373S (on ENST00000360851 / NM_001297672.2; = p.T408S on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.5); catalogued as COSV58985172; called by muse, mutect2, varscan2
- RGS22 | c.81C>G p.F27L | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62661491, COSV62666829; called by muse, mutect2, varscan2
- RIN3 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV53648277; called by muse, mutect2, varscan2
- RXFP4 | c.470G>C p.W157S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as COSV100562977, COSV58145079; called by muse, mutect2, varscan2
- RYR3 | c.1266C>A p.V422= | Splice Region (SNP) | VAF 53/193 reads (27%) | catalogued as COSV66788538; called by muse, mutect2, varscan2
- RYR3 | c.6989G>T p.G2330V (on ENST00000389232; = p.G2331V on NM_001036.6) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109649; called by muse, mutect2, varscan2
- SAMD4B | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58751477; called by muse, varscan2
- SEL1L2 | c.561T>G p.F187L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV53152093; called by muse, mutect2, varscan2
- SETX | c.4181C>T p.S1394L | Missense Mutation (SNP) | VAF 123/340 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV56384759; called by muse, mutect2, varscan2
- SHISA2 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1287524506, COSV60110762; called by muse, mutect2, varscan2
- SIGLEC10 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV59481562; called by muse, mutect2, varscan2
- SLC22A7 | c.434G>C p.R145T (on ENST00000372585 / NM_153320.2; = p.R143T on NM_006672.3) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV65354361; called by muse, mutect2, varscan2
- SLCO1C1 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56868350, COSV56872385; called by muse, mutect2, varscan2
- SPATA31E1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 111/328 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV57791361; called by muse, mutect2, varscan2
- SPDEF | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | catalogued as COSV65000948; called by muse, mutect2, varscan2
- SPECC1L | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58658367; called by muse, mutect2, varscan2
- SPTBN5 | c.2709T>G p.S903R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV58020446; called by muse, varscan2
- SSBP1 | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as COSV54681257; called by muse, mutect2, varscan2
- STAB2 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66338753; called by muse, mutect2, varscan2
- SUN5 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV62181084, COSV62181720; called by muse, mutect2, varscan2
- SYNE4 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as COSV53324621; called by muse, mutect2, varscan2
- TAFA2 | c.248C>G p.S83* | Nonsense Mutation (SNP) | VAF 7/134 reads (5%) | catalogued as COSV69178172; called by muse, mutect2
- TAPBP | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV69667272; called by muse, mutect2, varscan2
- TBATA | c.706T>C p.C236R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV54719082; called by muse, mutect2, varscan2
- TBC1D2B | c.2660A>G p.Y887C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV56038583; called by muse, mutect2, varscan2
- TBCD | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62800851; called by muse, mutect2, varscan2
- TCF20 | c.3614G>A p.G1205E | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV59491060; called by muse, mutect2, varscan2
- THBS2 | c.554C>A p.A185E | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs769719849, COSV64678774, COSV64682665; called by muse, mutect2, varscan2
- TMCC1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 95/495 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV67873006; called by muse, mutect2, varscan2
- TMEM132D | c.2840A>G p.H947R | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV67160334; called by muse, mutect2, varscan2
- TMEM132D | c.2150A>G p.D717G | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67160339; called by muse, mutect2, varscan2
- TOP3B | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64117348; called by muse, mutect2, varscan2
- TP53 | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 119/191 reads (62%) | catalogued as COSV52688866, COSV52766207; called by muse, mutect2, varscan2
- TRIM24 | c.1703A>C p.Q568P (on ENST00000343526 / NM_015905.3; = p.Q534P on NM_003852.4) | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.806); catalogued as COSV58972184, COSV58974125; called by muse, mutect2
- TRIP12 | c.4786G>C p.E1596Q | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.094); catalogued as COSV52263840; called by muse, mutect2, varscan2
- TTN | c.86980G>T p.E28994* (on ENST00000591111; = p.E21570* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 81/270 reads (30%) | catalogued as COSV60049839; called by muse, mutect2, varscan2
- TTN | c.77495C>G p.P25832R (on ENST00000591111; = p.P18408R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/332 reads (4%) | PolyPhen probably damaging (0.999); catalogued as COSV60049892; called by muse, mutect2
- TTN | c.64658T>A p.V21553D (on ENST00000591111; = p.V14129D on NM_003319.4) | Missense Mutation (SNP) | VAF 182/612 reads (30%) | PolyPhen possibly damaging (0.679); catalogued as COSV59959112, COSV60049944; called by muse, mutect2, varscan2
- TTN | c.52141G>A p.G17381R (on ENST00000591111; = p.G9957R on NM_003319.4) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV60049992; called by muse, mutect2, varscan2
- TTN | c.49496G>A p.R16499Q (on ENST00000591111; = p.R9075Q on NM_003319.4) | Missense Mutation (SNP) | VAF 37/117 reads (32%) | PolyPhen benign (0.314); catalogued as rs547224785, COSV60050043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.24032A>G p.H8011R (on ENST00000591111; = p.H7084R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/294 reads (32%) | PolyPhen benign (0.009); catalogued as COSV60050097; called by muse, mutect2, varscan2
- TTN | c.659G>C p.R220P | Missense Mutation (SNP) | VAF 55/193 reads (28%) | PolyPhen possibly damaging (0.906); catalogued as COSV60000521, COSV60050122; called by muse, mutect2, varscan2
- USH1C | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50017388; called by muse, mutect2, varscan2
- USH2A | c.6260A>T p.Q2087L | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV56367669; called by muse, mutect2, varscan2
- UXS1 | c.1169A>T p.Y390F | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as COSV51677291; called by muse, mutect2
- VENTX | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV58084527; called by muse, mutect2, varscan2
- VN1R1 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.052); catalogued as COSV58091031; called by muse, mutect2, varscan2
- WDR54 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 143/298 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV51963105; called by muse, varscan2
- WDR72 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV64746507; called by muse, mutect2, varscan2
- WT1 | c.573C>G p.S191R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV60071431; called by muse, mutect2, varscan2
- XDH | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV65148613; called by muse, mutect2, varscan2
- XYLT1 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54484150; called by muse, mutect2, varscan2
- ZC3H12C | c.1795C>A p.L599M | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs1433227668, COSV53708704; called by muse, mutect2, varscan2
- ZNF229 | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.992); catalogued as COSV52161812; called by muse, mutect2, varscan2
- ZNF532 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 111/200 reads (56%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV60173017; called by muse, mutect2, varscan2
- ZNF557 | c.421G>C p.G141R (on ENST00000414706 / NM_001044388.2; = p.G148R on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV53273830; called by muse, mutect2, varscan2
- ZNF787 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54418433; called by muse, mutect2
- ZNF804A | c.1607G>A p.C536Y | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV56447946; called by muse, mutect2, varscan2
- ZNF804A | c.1979C>G p.P660R | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as COSV56447959; called by muse, mutect2, varscan2
- ZNF804B | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 42/160 reads (26%) | catalogued as COSV60827351, COSV60837421; called by muse, mutect2, varscan2
- ZNF878 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV72155997; called by muse, mutect2, varscan2
- ANKRD45 | c.58del p.E20Rfs*29 | Frame Shift Del (DEL) | VAF 27/101 reads (27%) | called by mutect2, pindel, varscan2
- APOBR | c.2590G>T p.E864* (on ENST00000431282; = p.E873* on NM_018690.4) | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- DYNC2I1 | c.1523dup p.L508Ffs*8 | Frame Shift Ins (INS) | VAF 50/134 reads (37%) | called by mutect2, pindel, varscan2
- GOLGA8G | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- GRIK5 | c.1734C>A p.C578* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- LRRC8E | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRTM1 | c.381dup p.L128Tfs*83 | Frame Shift Ins (INS) | VAF 107/295 reads (36%) | called by mutect2, pindel, varscan2
- NPS | c.244dup p.T82Nfs*19 | Frame Shift Ins (INS) | VAF 114/259 reads (44%) | called by mutect2, varscan2
- OR8B4 | c.361dup p.R121Pfs*49 | Frame Shift Ins (INS) | VAF 54/126 reads (43%) | called by mutect2, pindel, varscan2
- TMEM101 | c.35_44del p.L12Sfs*59 | Frame Shift Del (DEL) | VAF 37/126 reads (29%) | called by mutect2, pindel, varscan2
- ZNF804A | c.1329_1337del p.M443_Y446delinsI | In Frame Del (DEL) | VAF 85/341 reads (25%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.2937C>T p.S979= | Silent (SNP) | VAF 176/274 reads (64%) | catalogued as COSV54955733; called by muse, mutect2, varscan2
- ADGRL3 | c.399T>C p.I133= (on ENST00000506720 / NM_001322402.2; = p.I65= on NM_015236.6) | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV72268365; called by muse, mutect2, varscan2
- ANGPTL1 | c.732T>A p.G244= | Silent (SNP) | VAF 68/222 reads (31%) | catalogued as COSV52366355; called by muse, mutect2, varscan2
- ANKRD26 | c.3165A>G p.L1055= | Silent (SNP) | VAF 61/139 reads (44%) | catalogued as COSV65775428, COSV65777230; called by muse, mutect2, varscan2
- AVPR1A | c.531G>T p.L177= | Silent (SNP) | VAF 50/165 reads (30%) | catalogued as COSV54546497; called by muse, mutect2, varscan2
- BAIAP3 | c.2385C>A p.A795= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV50103963; called by muse, mutect2
- CD22 | c.96C>T p.L32= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as COSV50052584; called by muse, mutect2, varscan2
- COL20A1 | c.249G>T p.G83= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV58917030, COSV58924573; called by muse, mutect2
- COL4A3 | c.1824A>T p.G608= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV67415488; called by muse, mutect2, varscan2
- COMMD7 | c.558G>T p.L186= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV54070169; called by muse, mutect2, varscan2
- DBR1 | c.231C>T p.L77= | Silent (SNP) | VAF 143/635 reads (23%) | catalogued as COSV53429745; called by muse, mutect2, varscan2
- DCSTAMP | c.510C>A p.T170= | Silent (SNP) | VAF 86/235 reads (37%) | catalogued as rs765227158, COSV52577620; called by muse, mutect2, varscan2
- DMD | c.10119C>T p.A3373= | Silent (SNP) | VAF 71/115 reads (62%) | catalogued as COSV58909986; called by muse, mutect2, varscan2
- DNAH11 | c.6666A>T p.R2222= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV60955245; called by muse, mutect2, varscan2
- DNAJC13 | c.3741C>T p.L1247= | Silent (SNP) | VAF 263/843 reads (31%) | catalogued as rs780003866, COSV53450403; called by muse, mutect2, varscan2
- DPPA2 | c.624T>G p.P208= | Silent (SNP) | VAF 72/155 reads (46%) | catalogued as COSV72118069; called by muse, mutect2, varscan2
- DSCAM | c.426C>A p.V142= | Silent (SNP) | VAF 76/140 reads (54%) | catalogued as COSV68624598, COSV68638199; called by muse, mutect2, varscan2
- EPO | c.69C>G p.L23= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV53161393; called by muse, varscan2
- EPS15L1 | c.1530G>A p.Q510= | Silent (SNP) | VAF 48/187 reads (26%) | catalogued as COSV50168648; called by muse, mutect2, varscan2
- ERF | c.1575C>G p.L525= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV55895839; called by muse, mutect2, varscan2
- ESPN | c.2217C>T p.L739= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1293011435, COSV64704334; called by muse, mutect2
- FAM135B | c.3501T>A p.P1167= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV52723926; called by muse, mutect2, varscan2
- FAM78A | c.573C>G p.T191= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as rs1409531498, COSV55992308; called by muse, mutect2, varscan2
- FBXO42 | c.1518G>C p.L506= | Silent (SNP) | VAF 91/200 reads (46%) | catalogued as COSV65045561; called by muse, mutect2, varscan2
- FNDC1 | c.1809C>T p.S603= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV51937580; called by muse, mutect2, varscan2
- FOXC2 | c.1371C>T p.H457= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV57444314; called by muse, mutect2, varscan2
- FOXN2 | c.246T>C p.V82= | Silent (SNP) | VAF 115/259 reads (44%) | catalogued as COSV61318038; called by muse, mutect2, varscan2
- FURIN | c.2325A>T p.S775= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV51576666; called by muse, mutect2, varscan2
- GPR151 | c.21A>G p.A7= | Silent (SNP) | VAF 67/152 reads (44%) | catalogued as COSV57037115; called by muse, mutect2, varscan2
- GRIN2A | c.4209G>C p.S1403= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as COSV58032105, COSV58042880; called by muse, mutect2, varscan2
- HNRNPL | c.1359C>T p.V453= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55492413, COSV55492565; called by muse, varscan2
- HSPBP1 | c.477G>T p.A159= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55334206; called by muse, mutect2
- IGKV6-21 | c.195C>T p.L65= | Silent (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- KANK4 | c.1575C>A p.G525= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as COSV62986724; called by muse, mutect2, varscan2
- KCNC2 | c.990G>T p.V330= | Silent (SNP) | VAF 63/196 reads (32%) | catalogued as rs201237451, COSV54368802, COSV54371035; called by muse, mutect2, varscan2
- LPO | c.21C>G p.L7= | Silent (SNP) | VAF 96/361 reads (27%) | catalogued as rs915639744, COSV51858708; called by muse, mutect2, varscan2
- LRFN1 | c.486C>T p.S162= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV50442446; called by muse, mutect2, varscan2
- LRRC40 | c.1107C>A p.I369= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV63942268; called by muse, mutect2, varscan2
- MAN2A1 | c.1161C>T p.P387= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as rs753323721, COSV54851444; called by muse, mutect2, varscan2
- MUC3A | c.7356C>G p.V2452= | Silent (SNP) | VAF 63/234 reads (27%) | catalogued as rs1563067680, COSV60215561; called by muse, mutect2, varscan2
- NCKAP5 | c.4116C>T p.I1372= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs759881752, COSV58443152; called by muse, mutect2, varscan2
- NOS3 | c.1494A>G p.E498= | Silent (SNP) | VAF 103/277 reads (37%) | catalogued as COSV52489607; called by muse, mutect2, varscan2
- OR2A25 | c.168C>A p.T56= | Silent (SNP) | VAF 103/220 reads (47%) | catalogued as COSV68717161; called by muse, mutect2, varscan2
- OR2G6 | c.597C>T p.L199= | Silent (SNP) | VAF 37/188 reads (20%) | catalogued as COSV100598337, COSV58573901; called by muse, mutect2, varscan2
- OR5D13 | c.861G>T p.L287= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV62333662; called by muse, mutect2, varscan2
- P3H1 | c.1959A>T p.S653= | Silent (SNP) | VAF 58/122 reads (48%) | catalogued as COSV52533681; called by muse, mutect2, varscan2
- PEX5 | c.1242C>T p.T414= (on ENST00000420616; = p.T406= on NM_000319.5) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV56954930, COSV99870896; called by muse, mutect2
- PLCH1 | c.2397A>T p.V799= (on ENST00000340059 / NM_001130960.2; = p.V811= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/187 reads (17%) | catalogued as COSV58196835; called by muse, mutect2, varscan2
- POU2F1 | c.1890A>G p.L630= (on ENST00000541643 / NM_001365848.1; = p.L653= on NM_002697.4) | Silent (SNP) | VAF 82/258 reads (32%) | catalogued as rs754961256, COSV54816928; called by muse, mutect2, varscan2
- PRELID2 | c.144A>G p.T48= (on ENST00000334744 / NM_182960.4; = p.T19= on NM_138492.6) | Silent (SNP) | VAF 104/213 reads (49%) | catalogued as rs577387442, COSV58279861; called by muse, mutect2, varscan2
- PSKH2 | c.576T>C p.Y192= | Silent (SNP) | VAF 17/180 reads (9%) | catalogued as COSV52610440; called by muse, mutect2
- PZP | c.4182T>C p.G1394= | Silent (SNP) | VAF 60/219 reads (27%) | catalogued as COSV54360278; called by muse, mutect2, varscan2
- RELN | c.4902T>C p.S1634= | Silent (SNP) | VAF 7/169 reads (4%) | catalogued as COSV58984554; called by muse, mutect2
- RIPOR1 | c.3465G>A p.L1155= (on ENST00000379312 / NM_001193522.2; = p.L1151= on NM_024519.4) | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV50224219; called by muse, mutect2
- SIGLEC10 | c.261G>T p.R87= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as COSV59481549; called by muse, mutect2, varscan2
- SLC22A2 | c.372C>T p.D124= | Silent (SNP) | VAF 55/149 reads (37%) | catalogued as rs1406195900, COSV65266308; called by muse, mutect2, varscan2
- SLC4A10 | c.711T>C p.R237= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV55777874; called by muse, mutect2, varscan2
- SOCS5 | c.309C>A p.T103= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as COSV100125547, COSV60604836; called by muse, mutect2, varscan2
- ST6GAL2 | c.975T>C p.S325= | Silent (SNP) | VAF 11/222 reads (5%) | catalogued as COSV62416593; called by muse, mutect2
- STX16 | c.954C>G p.V318= (on ENST00000371141 / NM_001001433.3; = p.V297= on NM_003763.6) | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as COSV56605736; called by muse, mutect2, varscan2
- SYMPK | c.2472G>A p.L824= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as rs1366995109, COSV55611529, COSV99841263; called by muse, mutect2, varscan2
- TMEM132B | c.732G>T p.S244= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as rs752253408, COSV54753397; called by muse, mutect2, varscan2
- TRANK1 | c.2433C>T p.I811= | Silent (SNP) | VAF 149/305 reads (49%) | catalogued as COSV57149798; called by muse, mutect2, varscan2
- TRAPPC1 | c.153G>A p.K51= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV58050216, COSV58050929; called by muse, mutect2, varscan2
- TRIM72 | c.909G>T p.V303= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1219232080, COSV59067753; called by muse, mutect2, varscan2
- TTN | c.95742C>A p.L31914= (on ENST00000591111; = p.L24490= on NM_003319.4) | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as COSV60049789; called by muse, mutect2, varscan2
- UNKL | c.1974C>T p.I658= (on ENST00000389221 / NM_001372107.1; = p.I154= on NM_001276414.2) | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs529314659, COSV50190029; called by muse, mutect2, varscan2
- VCPIP1 | c.3315G>A p.Q1105= | Silent (SNP) | VAF 85/256 reads (33%) | catalogued as COSV60047242; called by muse, mutect2, varscan2
- VEPH1 | c.1521A>T p.S507= | Silent (SNP) | VAF 108/703 reads (15%) | catalogued as COSV62878814; called by muse, mutect2, varscan2
- VPS13B | c.7299T>C p.S2433= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as COSV62141381; called by muse, mutect2, varscan2
- WDR49 | c.450A>T p.A150= (on ENST00000308378 / NM_001366158.1; = p.A491= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 234/634 reads (37%) | catalogued as COSV57708088; called by muse, mutect2, varscan2
- ZNF131 | c.1704C>A p.T568= (on ENST00000509156 / NM_001330707.2; = p.T534= on NM_003432.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV61002445; called by muse, mutect2, varscan2
- AC073310.1 | n.976C>A | RNA (SNP) | VAF 89/217 reads (41%) | called by muse, mutect2, varscan2
- SNORD116-20 | n.11T>A | RNA (SNP) | VAF 88/334 reads (26%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.16C>A | RNA (SNP) | VAF 69/243 reads (28%) | called by muse, mutect2, varscan2
- TRPM3 | c.1816-903A>G | Intron (SNP) | VAF 29/105 reads (28%) | catalogued as COSV62585600; called by muse, mutect2, varscan2
- TTN | c.10361-4215C>A | Intron (SNP) | VAF 82/313 reads (26%) | catalogued as rs397517820, COSV60050110; called by muse, mutect2, varscan2
